Gene-level copy-number profile of tumor specimen TCGA-FV-A4ZP-01A from TCGA case TCGA-FV-A4ZP, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 78.8 years (28,771 days).
Specimen TCGA-FV-A4ZP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.8c48f4c2-a9c8-4444-aeef-c3840e43333a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FV-A4ZP-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/efeed0c5-885e-4e17-85ce-555ab458bf8e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 413; copy number 2: 6,986; copy number 3: 18,605; copy number 4: 25,100; copy number 5: 2,063; copy number 6: 3,051; copy number 7: 1,100; copy number 8: 72; copy number 9: 205; copy number 11: 439; copy number 12: 1,172; copy number 13: 2; copy number 14: 452; copy number 18: 6; copy number 30: 16; copy number 31: 1; copy number 38: 35; copy number 49: 84; copy number 65: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FV-A4ZP-01A-12D-A25U-01): tumor purity 0.59, ploidy 3.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,428 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:81,431,731–83,162,930, 11 genes, copy number 11–18: AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235.
- chr7:86,876,906–119,179,149, 605 genes, copy number 13–65 (within-gene range 7–65) (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 11–14 (broad region; genes not listed).
- chr17:142,789–2,511,891, 99 genes, copy number 9 (broad region; genes not listed).
- chr17:19,020,656–20,322,973, 73 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr17:28,018,770–29,551,903, 106 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 413. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
